Somatic mutation profile of tumor specimen TARGET-10-PAREWZ-09A (aliquot TARGET-10-PAREWZ-09A-01D) from TARGET case TARGET-10-PAREWZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,692 days).
Specimen TARGET-10-PAREWZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3045ed7d-f9e9-490d-9eb5-cf2b9ac558fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREWZ-10A (Blood Derived Normal), aliquot TARGET-10-PAREWZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b428f45-af12-4b92-b27f-e10d747fac19

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/193 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- ADGRB1 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100030552; called by muse, mutect2, varscan2
- ANO5 | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV61082200; called by mutect2, varscan2
- ASXL3 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs776506817, COSV52473460; called by muse, mutect2, varscan2
- CELSR1 | c.2902G>T p.A968S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1440305496; called by muse, mutect2
- CLN8 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 263/436 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs143694317, COSV58671235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP11B2 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765921219, CM952252; called by muse, mutect2, varscan2
- HOXA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV57825097; called by muse, mutect2, varscan2
- NF1 | c.655-2A>G p.X219_splice | Splice Site (SNP) | VAF 85/184 reads (46%) | catalogued as CS000894, COSV62209260; called by muse, mutect2, varscan2
- PAXBP1 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs112853061, COSV51609052; called by muse, mutect2, varscan2
- PRR12 | c.1630C>T p.R544W (on ENST00000615927; = p.R1365W on NM_020719.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69816657; called by muse, mutect2, varscan2
- C15orf39 | c.2569C>A p.L857M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GTF3C1 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPP | c.1526T>A p.L509Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A6 | c.786C>A p.S262R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SLC52A1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- TLN2 | c.4507C>A p.H1503N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, varscan2
- TMEM47 | c.431A>T p.K144I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ZNF215 | c.1205C>A p.T402K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAM2 | c.1245A>C p.G415= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- OBSCN | c.16608G>A p.L5536= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- MTA3 | c.190+2598C>G | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.693-64G>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
- PPP1R1B | chr17:39622253 C>A | 5'Flank (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
